Gene-level copy-number profile of tumor specimen TCGA-36-2552-01A from TCGA case TCGA-36-2552, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 64.0 years (23,379 days).
Specimen TCGA-36-2552-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.386c8c8b-eba1-4840-b292-1b923029a5d5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-2552-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e6b77b40-0161-49d7-8049-97a30327162f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,525; copy number 2: 8,021; copy number 3: 20,190; copy number 4: 12,632; copy number 5: 6,845; copy number 6: 6,141; copy number 7: 3,220; copy number 8: 155; copy number 9: 54; copy number 10: 1; copy number 11: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-36-2552-01A-01D-1043-01): tumor purity 0.93, ploidy 3.86, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,449 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,003,711–195,026,370, 1 gene, copy number 8: AC010983.1.
- chr5:6,532,891–8,157,788, 36 genes, copy number 7: AC027334.1, LINC01018, NSUN2, SRD5A1, LINC02102, TENT4A, LINC02236, AC122710.2, MIR4278, LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1, AC091889.1, Metazoa_SRP, AC091951.4, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142, ADCY2, AC093305.1, C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC116361.1, AC091941.1, AC091912.2, AC091912.1.
- chr6:167,607–5,829,192, 120 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:5,609,227–31,637,771, 722 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:109,390,215–109,506,800, 5 genes, copy number 7 (within-gene range 5–7): PPIL6, SMPD2, MICAL1, ZBTB24, AL109947.1.
- chr7:62,275,361–62,275,678, 1 gene, copy number 8: AC128676.1.
- chr9:74,722,495–77,040,673, 34 genes, copy number 9–11 (within-gene range 3–11): TRPM6, RN7SKP47, RPSAP75, RNU6-445P, AL158825.1, C9orf40, CARNMT1-AS1, CARNMT1, AL158825.2, AL158825.3, NMRK1, OSTF1, Y_RNA, RNU6-1228P, AL158073.1, AL353780.1, OTX2P1, PCSK5, RBM22P5, RFK, RPSAP9, GCNT1, H3P32, PPIAP87, PRUNE2, PCA3, AL359314.1, AL390239.1, AL353637.2, DNAJB5P1, LYPLA2P3, AL353637.1, FOXB2, ATP5MFP3.
- chr10:44,712–108,941,310, 1,912 genes, copy number 7–8 (broad region; genes not listed).
- chr12:28,505,394–28,505,528, 1 gene, copy number 10: RNA5SP355.
- chr12:37,575,587–39,170,880, 20 genes, copy number 8: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1.
- chr16:11,555–10,841,544, 488 genes, copy number 7 (broad region; genes not listed).
- chr18:14,613,137–15,330,282, 27 genes, copy number 7: OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr18:23,004,564–25,953,468, 52 genes, copy number 7–9: RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1.
- chr18:27,932,879–29,361,963, 9 genes, copy number 7–8 (within-gene range 4–8): CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1.
- chr19:9,100,407–9,351,162, 18 genes, copy number 7 (within-gene range 4–7): OR7G2, OR7G1, OR7G15P, OR7G3, ZNF317, OR7D2, ELOCP29, OR7E16P, OR7E25P, OR7D4, OR7D1P, OR7E24, OR7E18P, OR7E19P, OR7H1P, ZNF699, AC011451.1, ZNF559.
- chr19:9,348,106–9,348,703, 1 gene, copy number 7: AC011451.2.
- chr19:27,638,483–27,646,483, 2 genes, copy number 7: ERVK-28, AC112702.1.

Autosomal genes at a single copy (total copy number 1): 106. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
